CPTAC case C3L-09189 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/abc71fa9-9b79-4653-8457-abd01c4b6515

Demographics
Sex at birth: male; Race: white; Year of birth: 1950; Vital status: Alive; Country of birth: Romania.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Fundus of stomach; Age at diagnosis: 72.2 years (26,377 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G2; Residual disease: R1; Days to last known disease status: 753 days (2.1 years); Progression or recurrence: no; Days to last follow up: 753 days (2.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.1 cm; Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 23.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 62 days; Days to treatment end: 215 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 62 days; Days to treatment end: 215 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 383.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 88; Cigarettes per day: 40; Tobacco smoking onset year: 1978; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-09189-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 34 days; Initial weight: 672 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-09189-21: Section location: Fundus; Percent tumor nuclei: 60; Percent necrosis: 5.
- Sample C3L-09189-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 34 days; Method of sample procurement: Blood Draw.
